Gene-level copy-number profile of tumor specimen ALCH-B4NQ-TTP1-A from ALCHEMIST case ALCH-B4NQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 37.1 years (13,558 days).
Specimen ALCH-B4NQ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file df9f5d1f-eaba-4cca-bcfd-3706d094fb57.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4NQ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/cce1d95a-0c8b-4296-82bc-3877a9775175

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 102; copy number 1: 5,487; copy number 2: 34,326; copy number 3: 12,793; copy number 4: 5,089; copy number 5: 748; copy number 6: 185; copy number 7: 14; copy number 8: 103; copy number 10: 7; copy number 95: 48.

Homozygous deletions (total copy number 0; autosomes only): 102 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:50,116,022–50,277,546, 12 genes (within-gene range 0–2): SEMA3F-AS1, SEMA3F, AC104450.1, GNAT1, SLC38A3, GNAI2, MIR5787, U73169.1, U73166.1, SEMA3B-AS1, SEMA3B, MIR6872.
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr4:68,614,419–68,670,652, 4 genes: AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr4:69,306,469–69,358,177, 2 genes (within-gene range 0–1): AC114786.3, AC114786.2.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr8:46,028,804–46,028,892, 1 gene: AC118650.1.
- chr8:84,162,118–84,164,564, 2 genes: TPM3P3, AC012400.1.
- chr8:133,325,997–133,571,940, 6 genes: KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3.
- chr8:141,968,091–142,407,028, 8 genes: AC104417.1, AC104417.2, AC103758.1, MIR4472-1, LINC00051, TSNARE1, RN7SL260P, AC134682.1.
- chr8:144,930,358–145,066,685, 8 genes: ZNF16, ZNF252P, AF235103.1, TMED10P1, ZNF252P-AS1, AF235103.2, AC139103.1, C8orf33.
- chr9:12,134–118,204, 10 genes: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4.
- chr15:25,178,738–25,257,027, 41 genes (within-gene range 0–1): SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1.
- chr15:81,633,426–82,046,119, 3 genes (within-gene range 0–1): AC104041.1, AC026956.1, MEX3B.
- chr17:61,393,456–61,413,280, 3 genes (within-gene range 0–3): TBX2-AS1, TBX2, LINC02875.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,103 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:23,801,885–23,868,290, 2 genes, copy number 5: HMGCL, FUCA1.
- chr5:58,198–37,753,435, 558 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr5:38,025,568–45,895,970, 114 genes, copy number 6 (broad region; genes not listed).
- chr5:104,383,298–105,392,970, 1 gene, copy number 5 (within-gene range 4–5): AC099520.1.
- chr5:104,917,492–107,011,052, 7 genes, copy number 5: AC091987.1, RAB9BP1, RNA5SP189, AC027313.1, AC114940.1, AC114940.2, LINC01950.
- chr7:52,891,837–56,323,601, 74 genes, copy number 5 (broad region; genes not listed).
- chr7:80,972,516–80,974,724, 1 gene, copy number 6: AC004972.1.
- chr7:90,167,590–92,971,299, 48 genes, copy number 95 (within-gene range 4–95): STEAP2, CFAP69, Y_RNA, AC002064.2, AC002064.1, FAM237B, GTPBP10, AC002064.3, CLDN12, AC006153.1, CDK14, AC002456.2, AC002456.1, TVP23CP1, AC002458.1, PTP4A1P3, FZD1, AC079760.2, NIPA2P1, AC079760.1, AC000058.1, MTERF1, AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P.
- chr7:94,524,204–96,377,920, 33 genes, copy number 6 (within-gene range 4–6): SGCE, PEG10, RPS3AP25, RNU6-956P, ATP5PBP2, GRPEL2P3, RN7SKP129, ARF1P1, PPP1R9A, HINT1P2, AC002429.1, PPP1R9A-AS1, RNU4-16P, PON1, AC004022.2, AC004022.1, PON3, PON2, AC005021.1, AC004012.1, ASB4, AC002451.2, AC002451.1, PDK4, DYNC1I1, AC002540.1, SLC25A13, MIR591, AC096775.1, AC084368.1, RNU6-532P, RNU6-364P, RNU7-188P.
- chr7:97,200,708–97,201,483, 1 gene, copy number 7: AC073900.1.
- chr7:125,229,579–126,424,185, 6 genes, copy number 5: AC019155.2, AC010099.1, AC010099.2, PPIAP93, AC003975.1, AC000372.1.
- chr7:128,954,180–129,611,630, 21 genes, copy number 5: TNPO3, RN7SL306P, ODCP, TPI1P2, AC018639.1, AC011005.2, AC011005.3, CYCSP20, AC011005.1, TSPAN33, RNY1P11, SMO, AC011005.4, AHCYL2, AC009244.1, CDC26P1, STRIP2, SNRPGP3, RNU1-72P, SMKR1, AC078846.1.
- chr7:130,730,697–130,791,724, 2 genes, copy number 5: KLF14, AC016831.5.
- chr7:130,822,868–130,939,661, 9 genes, copy number 5: AC016831.2, H4P1, AC016831.3, LINC00513, MIR29A, AC016831.1, MIR29B1, AC016831.4, AC058791.1.
- chr7:154,928,460–155,644,406, 26 genes, copy number 5 (within-gene range 3–5): PAXIP1-AS2, PAXIP1, AC093726.1, AC093726.2, PAXIP1-AS1, HTR5A-AS1, HTR5A, AC093726.3, AC092628.2, AC092628.1, RN7SKP280, AC099552.1, AC099552.3, AC099552.4, AC099552.2, AC144652.1, INSIG1, BLACE, AC008060.1, AC008060.4, AC008060.5, AC008060.3, EN2, CNPY1, AC009403.2, AC008060.2.
- chr7:157,138,916–159,233,377, 31 genes, copy number 5: UBE3C, RPS27AP12, AC004898.1, AC004975.1, AC004975.2, DNAJB6, AC006372.3, AC006372.1, AC006372.2, AC006372.4, PTPRN2, MIR153-2, AC005481.1, AC006003.1, PTPRN2-AS1, AC011899.2, AC011899.3, AC011899.1, MIR595, AC078942.1, LINC01022, MIR5707, THAP5P1, NCAPG2, AC019084.1, ESYT2, DYNC2I1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.
- chr8:101,686,542–102,124,907, 1 gene, copy number 6 (within-gene range 4–6): NCALD.
- chr8:101,847,256–101,872,549, 2 genes, copy number 6: AP001329.1, PDCL3P2.
- chr8:106,215,763–106,268,741, 2 genes, copy number 5: SLC16A14P1, AC027031.1.
- chr8:109,539,711–111,757,710, 21 genes, copy number 6–7: EBAG9, SYBU, AC079061.1, AC023245.2, AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7.
- chr8:117,520,713–119,246,848, 14 genes, copy number 6–10: MED30, RPS10P16, EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1.
- chr8:124,474,880–131,317,632, 94 genes, copy number 6–8 (broad region; genes not listed).
- chr8:134,722,947–135,742,495, 15 genes, copy number 8: AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56, LINC01591, AC040914.1, KHDRBS3, MAPRE1P1, RNU1-35P.
- chr8:140,505,813–141,002,216, 9 genes, copy number 7 (within-gene range 4–7): AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1.
- chr16:79,603,572–79,827,150, 7 genes, copy number 5: AC009159.2, AC009159.3, AC009159.1, AC009159.4, LINC01229, MAFTRR, LINC01228.
- chr21:43,092,956–43,168,646, 2 genes, copy number 6–7 (within-gene range 1–7): U2AF1, AP001631.2.
- chr21:43,159,066–43,172,805, 2 genes, copy number 7: AP001631.1, CRYAA.

Autosomal genes at a single copy (total copy number 1): 5,390. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
